Somatic mutation profile of tumor specimen ALCH-B3JM-TTP1-A (aliquot ALCH-B3JM-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3JM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.0 years (28,140 days).
Specimen ALCH-B3JM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d3992ba-996e-4a99-b23e-4277f86c04ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JM-NB1-A (Blood Derived Normal), aliquot ALCH-B3JM-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b49c6184-a904-4632-bc1d-efbfdad417b7

The open-access MAF lists 109 somatic variants for this specimen: 73 protein-altering or splice-affecting, 25 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 25, Nonsense Mutation 4, 5'Flank 4, Intron 3, Splice Site 2, 5'UTR 2, RNA 1, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 30/546 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS20 | c.3953G>A p.S1318N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1014463225; called by muse, mutect2
- ADAMTSL1 | c.3599T>A p.L1200Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65888002; called by muse, mutect2
- CENPE | c.7514G>A p.R2505K | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs1395167430; called by muse, mutect2
- CLEC16A | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328266; called by muse, mutect2
- FMO2 | c.1045A>G p.M349V | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs141615057; called by muse, mutect2
- H2BC5 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1358692800, COSV56800766, COSV56803159, COSV99175306; called by muse, mutect2
- ISL1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57934286; called by muse, mutect2
- ITPR3 | c.4324G>C p.E1442Q | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1261500702, COSV100967593; called by muse, mutect2
- MAP4K4 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV56324517; called by muse, mutect2
- MINK1 | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1286896604; called by muse, mutect2
- MROH9 | c.1735-1G>A p.X579_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100883418; called by mutect2, varscan2
- MYBPC1 | c.1636G>C p.E546Q (on ENST00000550270 / NM_206820.2; = p.E571Q on NM_002465.4) | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62252438, COSV62253573; called by muse, mutect2
- PCDHB8 | c.1321C>A p.L441M | Missense Mutation (SNP) | VAF 36/1376 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1425060020; called by muse, mutect2
- PPARD | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61099682; called by muse, mutect2
- RPS6KC1 | c.116G>C p.R39P | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100874071; called by muse, mutect2
- RYR2 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV63717975; called by muse, mutect2
- SIL1 | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 32/752 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV54533028; called by muse, mutect2
- SPG7 | c.1204G>A p.E402K (on ENST00000268704; = p.E409K on NM_003119.4) | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD152072, COSV51950394; called by muse, mutect2
- SRGAP2 | c.2870G>T p.R957L (on ENST00000624873 / NM_001170637.4; = p.R958L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV55340013; called by muse, mutect2
- TH | c.520G>T p.A174S (on ENST00000381178 / NM_199292.3; = p.A143S on NM_000360.4) | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV60767017; called by muse, mutect2
- TLN1 | c.7608G>T p.E2536D | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs751547692; called by muse, mutect2
- TMEM154 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs771482157; called by muse, mutect2, varscan2
- VCAN | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs749552627; called by muse, mutect2
- ACAN | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- ADGRL2 | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 26/424 reads (6%) | called by muse, mutect2
- AP1G1 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ATG3 | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- CENPL | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- CFAP46 | c.2973C>G p.I991M | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- CPEB1 | c.1743G>T p.Q581H (on ENST00000617958; = p.Q516H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- DAGLB | c.1904T>A p.M635K | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DISP1 | c.1608C>G p.I536M | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- DISP1 | c.2908A>T p.N970Y | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2
- DNAJC19 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DNMBP | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- DOP1B | c.2647C>G p.Q883E | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FERMT3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/180 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2
- FERMT3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.968); called by muse, mutect2
- FH | c.508G>C p.G170R | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR83 | c.464T>A p.L155Q | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- HECW1 | c.2096G>T p.S699I | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- HPS6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 34/522 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- IGKV2-24 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 22/539 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- IL1RAPL2 | c.84G>T p.V28= | Splice Region (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- IPO4 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- KCTD16 | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LILRA1 | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPO | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); called by muse, mutect2
- LRRC32 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- MFGE8 | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.214); called by muse, mutect2
- NLRP10 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T33 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- PKDREJ | c.5845C>G p.L1949V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLCD1 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLXNA4 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- PPP1R12A | c.1906C>G p.P636A | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2
- PRKD3 | c.1268T>C p.M423T | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- S1PR5 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC9B1P1 | n.876-1G>A | Splice Site (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- SSC5D | c.4060C>G p.L1354V | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ST7L | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2
- SYNPO2 | c.2717C>G p.S906C | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT11 | c.924G>T p.M308I | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TAF7 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 8/206 reads (4%) | called by muse, mutect2
- TBC1D9 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- TMEM132C | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2
- TRIM42 | c.442A>C p.M148L | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VPS35L | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF469 | c.7738G>A p.E2580K (on ENST00000437464; = p.E2608K on NM_001367624.2) | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.343); called by muse, mutect2
- ZNF513 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZNF534 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF579 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2
- ANKRD1 | c.834C>G p.L278= | Silent (SNP) | VAF 39/664 reads (6%) | catalogued as COSV100865381; called by muse, mutect2
- CDH7 | c.1737C>A p.T579= | Silent (SNP) | VAF 30/682 reads (4%) | catalogued as COSV59888702; called by muse, mutect2
- CNGA4 | c.1335G>C p.L445= | Silent (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- EIPR1 | c.177C>G p.V59= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- GJC1 | c.729C>G p.L243= | Silent (SNP) | VAF 13/343 reads (4%) | called by muse, mutect2
- HFE | c.471A>T p.A157= | Silent (SNP) | VAF 19/389 reads (5%) | catalogued as CD072430; called by muse, mutect2
- IKBKB | c.1077G>T p.L359= | Silent (SNP) | VAF 20/433 reads (5%) | called by muse, mutect2
- IL17RE | c.78T>A p.I26= | Silent (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- KIF3C | c.978C>G p.L326= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV99267178; called by muse, mutect2
- LCT | c.5073C>T p.L1691= | Silent (SNP) | VAF 21/493 reads (4%) | called by muse, mutect2
- LETM1 | c.423C>T p.Y141= | Silent (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
- LILRA1 | c.78C>A p.L26= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- LRIT1 | c.441C>A p.P147= | Silent (SNP) | VAF 18/329 reads (5%) | called by muse, mutect2
- MCOLN1 | c.495C>T p.L165= | Silent (SNP) | VAF 19/460 reads (4%) | called by muse, mutect2
- MSL1 | c.18G>T p.A6= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV68324018; called by muse, mutect2, varscan2
- NME9 | c.831C>A p.A277= (on ENST00000333911 / NM_001349024.2; = p.A216= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as COSV58617305; called by muse, mutect2
- OR2AJ1 | c.189C>T p.L63= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- POLH | c.849A>G p.E283= | Silent (SNP) | VAF 26/309 reads (8%) | called by muse, mutect2
- PRUNE2 | c.1287A>T p.G429= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.2320C>T p.L774= | Silent (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- TBC1D14 | c.420C>G p.L140= | Silent (SNP) | VAF 29/400 reads (7%) | catalogued as rs1170470141; called by muse, mutect2
- USP40 | c.2151C>T p.L717= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- ZBTB4 | c.2187G>T p.G729= | Silent (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- ZNF469 | c.7830G>A p.L2610= (on ENST00000437464; = p.L2638= on NM_001367624.2) | Silent (SNP) | VAF 24/546 reads (4%) | called by muse, mutect2
- ZNF749 | c.465G>T p.T155= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as rs369534341; called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621900 G>T | 5'Flank (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- ASS1 | c.-5-284G>A | Intron (SNP) | VAF 37/365 reads (10%) | catalogued as COSV61690030; called by muse, mutect2, varscan2
- CPNE6 | c.865-14C>G | Intron (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2
- LY9 | c.454+1804C>T | Intron (SNP) | VAF 18/233 reads (8%) | catalogued as COSV54432148; called by muse, mutect2
- MTR | c.-42C>G | 5'UTR (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- PRR27 | n.330A>G | RNA (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128554 C>T | 5'Flank (SNP) | VAF 8/50 reads (16%) | catalogued as rs1379817873; called by muse, mutect2
- RAB17 | chr2:237591172 G>A | 5'Flank (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- TFR2 | c.-16A>C | 5'UTR (SNP) | VAF 11/326 reads (3%) | catalogued as COSV50514166, COSV99355772; called by muse, mutect2
- USP2 | chr11:119381864 G>A | 5'Flank (SNP) | VAF 33/362 reads (9%) | catalogued as rs1232311368; called by muse, mutect2
- ZNF827 | c.*450G>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
